Somatic mutation profile of tumor specimen TCGA-B5-A0JN-01A (aliquot TCGA-B5-A0JN-01A-11D-A10B-09) from TCGA case TCGA-B5-A0JN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-B5-A0JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37e6abd2-4dc2-4410-89e0-7c11d855a747.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JN-10A (Blood Derived Normal), aliquot TCGA-B5-A0JN-10A-01D-A10O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e94dbe5b-68d7-407d-9f51-85ed91b3270f

The open-access MAF lists 151 somatic variants for this specimen: 116 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 32, Splice Site 6, Nonsense Mutation 6, In Frame Del 3, Splice Region 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1362_1376del p.Q455_K459del (on ENST00000521381 / NM_181523.3; = p.Q185_K189del on NM_181504.4) | In Frame Del (DEL) | VAF 31/51 reads (61%) | hotspot (GDC flag); catalogued as COSV57141082; called by mutect2, pindel, varscan2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 32/44 reads (73%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.5835T>A p.N1945K (on ENST00000272895 / NM_173076.3; = p.N1627K on NM_015657.3) | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55977730; called by muse, mutect2
- ACAP2 | c.1780G>C p.D594H | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV58756493; called by muse, mutect2
- ACSL3 | c.263T>C p.L88S | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1174405839, COSV62484971; called by muse, mutect2, varscan2
- ACSM4 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV68069651; called by muse, mutect2, varscan2
- ADAM22 | c.2485C>T p.R829* | Nonsense Mutation (SNP) | VAF 37/56 reads (66%) | catalogued as COSV55991802; called by muse, mutect2, varscan2
- ADGRB3 | c.1220G>A p.S407N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV65422681; called by muse, mutect2, varscan2
- ADGRF1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV51948144; called by muse, mutect2, varscan2
- APOB | c.5582G>T p.G1861V | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51955122; called by muse, mutect2, varscan2
- ARHGAP35 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV68336111; called by muse, mutect2, varscan2
- ATF4 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 88/144 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs754079438, COSV57480886; called by muse, mutect2, varscan2
- ATP8B1 | c.141_152del p.N48_A51del | In Frame Del (DEL) | VAF 74/103 reads (72%) | catalogued as COSV52180773; called by mutect2, pindel, varscan2
- BACE1 | c.943-2A>T p.X315_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV57286625; called by muse, mutect2, varscan2
- BSG | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV61077842; called by muse, mutect2, varscan2
- CBX3 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV61761926; called by muse, mutect2
- CCBE1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67951725; called by muse, mutect2
- CCDC170 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); catalogued as COSV53347041; called by muse, mutect2
- CDH23 | c.4161G>C p.L1387F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV56493159; called by muse, mutect2
- CIT | c.4862A>G p.N1621S | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.306); catalogued as COSV55884912; called by muse, mutect2, varscan2
- CNOT1 | c.4324C>T p.H1442Y | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV55322937; called by muse, mutect2, varscan2
- CNOT1 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 13/172 reads (8%) | catalogued as COSV57781565; called by muse, mutect2
- COPS6 | c.785C>G p.A262G | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV57999294; called by muse, mutect2, varscan2
- COX5B | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51481209; called by muse, mutect2, varscan2
- CPNE5 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV55200471; called by muse, mutect2, varscan2
- CYP4F22 | c.1418+2T>A p.X473_splice | Splice Site (SNP) | VAF 27/106 reads (25%) | catalogued as COSV54112305; called by muse, mutect2, varscan2
- DAZAP1 | c.62C>G p.T21R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51836589; called by muse, mutect2, varscan2
- DAZL | c.241G>C p.G81R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51713676, COSV51714720; called by muse, mutect2, varscan2
- DOCK9 | c.5240G>A p.R1747Q (on ENST00000376460 / NM_001366676.2; = p.R1748Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as rs559984159, COSV59631183; called by muse, mutect2, varscan2
- DSG2 | c.2129A>G p.E710G | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV55203498; called by muse, mutect2
- DTX4 | c.1570A>C p.S524R | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV57095669; called by muse, mutect2
- EHD1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV57737011; called by muse, mutect2, varscan2
- EIF2AK3 | c.1948G>C p.G650R | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57552601; called by muse, mutect2
- EIF4G3 | c.447G>C p.Q149H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV51695398, COSV99059206; called by muse, mutect2
- EME1 | c.277T>A p.F93I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56813388; called by muse, mutect2, varscan2
- FHDC1 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as COSV52603587; called by muse, mutect2, varscan2
- FKBP8 | c.900G>T p.E300D (on ENST00000222308 / NM_001308373.2; = p.E301D on NM_012181.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.414); catalogued as COSV55894379; called by muse, mutect2, varscan2
- FO393400.1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 100/175 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs376952466, COSV54071729; called by muse, mutect2, varscan2
- GLB1L2 | c.1109-1G>A p.X370_splice | Splice Site (SNP) | VAF 45/125 reads (36%) | catalogued as COSV60280934; called by muse, mutect2, varscan2
- GNE | c.161C>T p.S54F (on ENST00000396594 / NM_001128227.3; = p.S23F on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64953269; called by muse, mutect2, varscan2
- GNL1 | c.1583-2A>G p.X528_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV64921524; called by muse, mutect2, varscan2
- GP1BA | c.1382G>T p.S461I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.18); catalogued as COSV56701016; called by muse, mutect2, varscan2
- GPR156 | c.1685C>A p.A562D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV59942734; called by muse, mutect2
- GPS2 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 53/73 reads (73%) | catalogued as COSV59753586; called by muse, mutect2, varscan2
- GRID1 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV60056657; called by muse, mutect2, varscan2
- GRM1 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV51146174, COSV51367846; called by muse, mutect2, varscan2
- HNRNPA1 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV52939089; called by muse, mutect2
- KCNG4 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57586257; called by muse, mutect2, varscan2
- KCNN2 | c.1279C>T p.L427F (on ENST00000264773; = p.L639F on NM_021614.4) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53300238; called by muse, mutect2, varscan2
- KIAA0100 | c.6087C>G p.F2029L | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV56384220; called by muse, mutect2
- KNG1 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53981388; called by muse, mutect2
- KSR2 | c.377A>C p.Q126P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV60396153; called by muse, mutect2, varscan2
- LRRC61 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.551); catalogued as rs777197763, COSV56232189; called by muse, mutect2, varscan2
- MAP4 | c.3066+1G>A p.X1022_splice | Splice Site (SNP) | VAF 11/95 reads (12%) | catalogued as COSV53143353; called by muse, mutect2, varscan2
- MAP4K1 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV50264700; called by muse, mutect2, varscan2
- MARCO | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59059301; called by muse, mutect2, varscan2
- MCC | c.2367G>C p.K789N | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56737087; called by muse, mutect2
- MED14 | c.3647T>G p.M1216R | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV61358787; called by muse, mutect2, varscan2
- MFSD6 | c.1937T>C p.V646A | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1369617960, COSV55625824; called by muse, mutect2, varscan2
- NAV1 | c.3346C>G p.Q1116E | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV55227411; called by muse, mutect2, varscan2
- NCF4 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV50629170; called by muse, mutect2
- NCKAP1L | c.1630C>T p.H544Y | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53206909; called by muse, mutect2, varscan2
- NCOA7 | c.41A>T p.Y14F | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.956); catalogued as COSV57660875; called by muse, mutect2, varscan2
- NKX2-2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs753385322, COSV65820122; called by muse, mutect2, varscan2
- NKX6-1 | c.787G>C p.G263R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV55686086; called by muse, mutect2, varscan2
- NLN | c.1438G>C p.V480L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66767401; called by muse, mutect2, varscan2
- NPHP1 | c.525A>G p.K175= | Splice Region (SNP) | VAF 22/264 reads (8%) | catalogued as COSV57212173; called by muse, mutect2
- NUSAP1 | c.1173A>T p.Q391H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV52973770; called by muse, mutect2, varscan2
- OAS2 | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV60804748; called by muse, mutect2, varscan2
- OR10J3 | c.474T>G p.I158M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV59955762; called by muse, mutect2, varscan2
- OR2M7 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58740967; called by mutect2, varscan2
- OR2T4 | c.1032A>C p.Q344H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV63545229; called by muse, mutect2, varscan2
- OSBPL6 | c.2186T>G p.V729G | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV51931729; called by muse, mutect2
- PDE8A | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.184); catalogued as rs753388144, COSV59641008; called by muse, mutect2, varscan2
- PHB | c.456C>G p.D152E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55931952; called by muse, mutect2, varscan2
- PLEKHG1 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as COSV62051582; called by muse, mutect2, varscan2
- PRAM1 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs1396379199, COSV55317464; called by muse, mutect2, varscan2
- PRKG1 | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64774884, COSV64778944; called by muse, mutect2, varscan2
- RAI1 | c.4237A>G p.M1413V | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs746444277, COSV55399890; called by muse, mutect2, varscan2
- RASGRF2 | c.3475_3488del p.T1159Yfs*2 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | catalogued as COSV54140852; called by mutect2, pindel, varscan2
- RB1CC1 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV50278999; called by muse, mutect2, varscan2
- RBSN | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53795847; called by muse, mutect2, varscan2
- RCVRN | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56842666; called by muse, mutect2, varscan2
- RMC1 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52575050; called by muse, mutect2
- RREB1 | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV58566508; called by muse, mutect2, varscan2
- RYR2 | c.2533A>T p.T845S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV63662920; called by muse, mutect2, varscan2
- SAMD9L | c.4360T>C p.S1454P | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59085843; called by muse, mutect2, varscan2
- SHOX2 | c.452A>C p.Q151P (on ENST00000441443 / NM_006884.3; = p.Q175P on NM_003030.4) | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67463879, COSV67464859; called by muse, varscan2
- SLC1A3 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV54320134, COSV54320886; called by muse, mutect2, varscan2
- SLC7A13 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52536253, COSV52537671; called by muse, mutect2, varscan2
- SORBS1 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV53366846; called by muse, mutect2
- ST8SIA4 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 12/164 reads (7%) | PolyPhen benign (0.049); catalogued as COSV51517416; called by muse, mutect2
- SUGCT | c.1103G>T p.G368V (on ENST00000335693 / NM_001193313.2; = p.G394V on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/684 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV59335398; called by muse, mutect2
- TENM1 | c.6370A>T p.T2124S | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV64445065; called by muse, mutect2
- THOC6 | c.673T>C p.C225R | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50188292; called by muse, mutect2, varscan2
- TIMM50 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV58680913; called by muse, mutect2, varscan2
- TMC8 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs142161296; called by muse, mutect2, varscan2
- TRIM71 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755247607, COSV67472840; called by muse, mutect2, varscan2
- TRPC4AP | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52684984; called by muse, mutect2, varscan2
- TTN | c.8353G>A p.G2785R (on ENST00000591111; = p.G2739R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | PolyPhen possibly damaging (0.788); catalogued as COSV60243403; called by muse, mutect2
- TTN | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 53/95 reads (56%) | PolyPhen probably damaging (0.974); catalogued as COSV59997704, COSV60382893; called by muse, mutect2, varscan2
- TYW1 | c.1698+1G>A p.X566_splice | Splice Site (SNP) | VAF 4/73 reads (5%) | catalogued as COSV62756686; called by muse, mutect2
- UFC1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.136); catalogued as COSV57091593; called by muse, mutect2, varscan2
- WDR72 | c.1602C>A p.C534* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV64741674, COSV64754512; called by muse, mutect2, varscan2
- WDR75 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59107219; called by muse, mutect2, varscan2
- WNT8B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1363072385, COSV59326127, COSV59326922; called by muse, mutect2
- ZMPSTE24 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs772647434, COSV65640322; called by muse, mutect2, varscan2
- ZNF273 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV60401133; called by muse, mutect2, varscan2
- ZNF708 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV100803116, COSV63609015; called by muse, mutect2, varscan2
- AMBRA1 | c.1194_1204del p.L399Pfs*3 (on ENST00000458649 / NM_001367468.1; = p.L309Pfs*3 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- BRDT | c.283_315del p.I95_C105del | In Frame Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- KIR3DL3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2
- MRC1 | c.4034T>C p.I1345T | Missense Mutation (SNP) | VAF 106/390 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PCDHGA11 | c.2433+8T>A | Splice Region (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- REV1 | c.1920dup p.I641Yfs*19 | Frame Shift Ins (INS) | VAF 43/284 reads (15%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2531G>T p.G844V | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ADPRS | c.483C>T p.S161= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs11538708, COSV52882310; called by muse, mutect2, varscan2
- ALMS1 | c.7398A>G p.S2466= | Silent (SNP) | VAF 16/262 reads (6%) | catalogued as COSV52523297; called by muse, mutect2
- ATAD5 | c.1353T>G p.G451= | Silent (SNP) | VAF 30/42 reads (71%) | catalogued as COSV58979825; called by muse, mutect2, varscan2
- BAAT | c.1128G>A p.T376= | Silent (SNP) | VAF 84/109 reads (77%) | catalogued as rs202090808, COSV52291190; called by muse, mutect2, varscan2
- BSN | c.1662G>A p.K554= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56528916; called by muse, mutect2
- C1QB | c.237G>A p.G79= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV59246203; called by muse, mutect2, varscan2
- CD1C | c.159G>A p.L53= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV63807827; called by muse, mutect2, varscan2
- DAGLA | c.270C>T p.P90= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV57200515; called by muse, mutect2
- GFAP | c.982C>T p.L328= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV53654081; called by muse, mutect2
- KIAA0753 | c.2076G>A p.L692= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV63234806; called by muse, mutect2, varscan2
- KIF5A | c.672C>T p.L224= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs770896632, COSV54059650; called by muse, mutect2, varscan2
- LAMA2 | c.1176A>C p.T392= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV69001123; called by muse, mutect2
- MGAT5 | c.99C>T p.T33= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV56101647; called by muse, mutect2, varscan2
- MRGPRX4 | c.144G>T p.V48= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV58591859; called by muse, mutect2, varscan2
- NEK8 | c.1173G>C p.V391= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV52043446, COSV52049139; called by muse, mutect2, varscan2
- OR2M7 | c.96G>C p.L32= | Silent (SNP) | VAF 48/395 reads (12%) | called by mutect2, varscan2
- OR4N2 | c.462C>T p.V154= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs928989624, COSV60055401; called by muse, mutect2, varscan2
- OR8B2 | c.795A>T p.G265= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV66665577; called by muse, mutect2
- PKD1L1 | c.3330G>C p.G1110= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV56979490, COSV56979741; called by muse, mutect2, varscan2
- PLEKHG3 | c.3192C>T p.P1064= (on ENST00000394691; = p.P1120= on NM_001308147.2) | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as COSV55984393, COSV99906705; called by muse, mutect2, varscan2
- PPEF1 | c.880T>C p.L294= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV62996928; called by muse, mutect2
- SCN1A | c.1575T>G p.S525= | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as COSV57690040; called by muse, mutect2
- SIDT2 | c.2445G>A p.L815= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV54060650, COSV54061365; called by muse, mutect2, varscan2
- SLC12A9 | c.597G>C p.L199= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV51937574; called by mutect2, varscan2
- SLC37A2 | c.1020C>T p.F340= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as rs771588739, COSV53525778; called by muse, mutect2, varscan2
- SLC5A5 | c.999C>T p.F333= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs754204356, COSV55835903; called by muse, mutect2, varscan2
- STAG3 | c.1722G>T p.V574= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV57935573; called by muse, mutect2, varscan2
- TAFA1 | c.93C>T p.F31= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV72037416, COSV72041223; called by muse, mutect2, varscan2
- TIE1 | c.2349G>T p.L783= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV65249539; called by muse, varscan2
- TPRG1 | c.108G>A p.P36= | Silent (SNP) | VAF 58/270 reads (21%) | catalogued as rs1030451513, COSV61464529, COSV61469234; called by muse, mutect2, varscan2
- TTN | c.36246T>C p.G12082= (on ENST00000591111; = p.G4658= on NM_003319.4) | Silent (SNP) | VAF 78/160 reads (49%) | catalogued as COSV60382832; called by muse, mutect2, varscan2
- ZNF24 | c.900C>G p.V300= | Silent (SNP) | VAF 14/326 reads (4%) | catalogued as COSV54349485; called by muse, mutect2
- IGHV1-12 | n.85G>A | RNA (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.950C>T | RNA (SNP) | VAF 16/58 reads (28%) | catalogued as COSV55601513; called by muse, mutect2, varscan2
- TRAK1 | c.1963+259del | Intron (DEL) | VAF 22/56 reads (39%) | catalogued as COSV58265111; called by mutect2, pindel, varscan2
